Somatic mutation profile of tumor specimen TCGA-HU-A4HB-01A (aliquot TCGA-HU-A4HB-01A-12D-A25D-08) from TCGA case TCGA-HU-A4HB, project TCGA-STAD (Stomach Adenocarcinoma). Sex at birth: male; Vital status: Dead; Primary diagnosis: Carcinoma, diffuse type; Tissue or organ of origin: Gastric antrum; AJCC pathologic stage: Stage IIB; Tumor grade: G3; Age at diagnosis: 68.8 years (25,131 days).
Specimen TCGA-HU-A4HB-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 9c5c03a8-465c-4de7-9284-249fd5b48e3f.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-HU-A4HB-10A (Blood Derived Normal), aliquot TCGA-HU-A4HB-10A-01D-A25E-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/7ec90044-c03b-4da1-a639-9bec59ea0bb2

The open-access MAF lists 14 somatic variants for this specimen: 12 protein-altering or splice-affecting, 1 silent, 1 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 11, Intron 1, Silent 1, Splice Site 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- ARVCF | c.2107G>T p.A703S | Missense Mutation (SNP) | VAF 12/140 reads (9%) | SIFT tolerated (0.15); PolyPhen possibly damaging (0.627); catalogued as COSV99258730; called by muse, mutect2
- CCDC112 | c.385T>G p.F129V | Missense Mutation (SNP) | VAF 5/93 reads (5%) | SIFT tolerated (0.48); PolyPhen benign (0.009); catalogued as COSV101100481; called by muse, mutect2
- GART | c.1735C>G p.P579A | Missense Mutation (SNP) | VAF 7/159 reads (4%) | SIFT tolerated (0.85); PolyPhen benign (0); catalogued as rs1465301930, COSV67818121; called by muse, mutect2
- GNAS | c.1631G>A p.R544Q | Missense Mutation (SNP) | VAF 5/26 reads (19%) | SIFT tolerated, low confidence (0.52); PolyPhen benign (0.003); catalogued as COSV100007003; called by muse, mutect2
- LSM2 | c.256G>T p.A86S | Missense Mutation (SNP) | VAF 10/248 reads (4%) | SIFT tolerated (0.4); PolyPhen benign (0.003); catalogued as COSV100989565; called by muse, mutect2
- PPP4R1 | c.1147A>G p.M383V (on ENST00000400556 / NM_001042388.3; = p.M366V on NM_005134.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 6/85 reads (7%) | SIFT tolerated (0.37); PolyPhen benign (0); catalogued as rs1368495967; called by muse, mutect2
- RGS7 | c.1128A>C p.E376D | Missense Mutation (SNP) | VAF 7/113 reads (6%) | SIFT tolerated (0.58); PolyPhen benign (0.001); catalogued as COSV100468896; called by muse, mutect2
- RHPN2 | c.694A>C p.T232P | Missense Mutation (SNP) | VAF 4/37 reads (11%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.895); catalogued as COSV99577833; called by muse, mutect2, varscan2
- SART3 | c.1895A>G p.K632R (on ENST00000228284; = p.K614R on NM_014706.4) | Missense Mutation (SNP) | VAF 10/99 reads (10%) | SIFT tolerated (0.07); PolyPhen benign (0.038); catalogued as COSV99934214; called by mutect2, varscan2
- TRPC7 | c.178C>T p.R60W | Missense Mutation (SNP) | VAF 9/242 reads (4%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.998); catalogued as rs1391101274, COSV61459664; called by muse, mutect2
- ZNF512B | c.2427+1G>A p.X809_splice | Splice Site (SNP) | VAF 7/76 reads (9%) | catalogued as COSV99412326; called by muse, mutect2
- SGK1 | c.859T>G p.L287V | Missense Mutation (SNP) | VAF 5/71 reads (7%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.654); called by muse, mutect2
- WSCD2 | c.531C>T p.A177= | Silent (SNP) | VAF 8/76 reads (11%) | catalogued as rs368739228; called by mutect2, varscan2
- CLASP1 | c.2734-775G>T | Intron (SNP) | VAF 6/137 reads (4%) | called by muse, mutect2
